Somatic mutation profile of tumor specimen TCGA-17-Z033-01A (aliquot TCGA-17-Z033-01A-01W-0746-08) from TCGA case TCGA-17-Z033, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z033-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2da5bbe8-ec5c-4726-b380-00a4da8033d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z033-11A (Solid Tissue Normal), aliquot TCGA-17-Z033-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11ba710c-f1ea-4031-b71d-2278b88965c8

The open-access MAF lists 170 somatic variants for this specimen: 124 protein-altering or splice-affecting, 45 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 45, Nonsense Mutation 4, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.77A>G p.Q26R | Missense Mutation (SNP) | VAF 5/36 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101229454, COSV67961584, COSV67961602; called by muse, mutect2, varscan2
- AMER1 | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57663081; called by muse, mutect2, varscan2
- ARID4B | c.3634C>A p.P1212T | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as rs1558167710; called by muse, mutect2, varscan2
- ATP9B | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.802); catalogued as rs1357235990, COSV99067014; called by muse, mutect2, varscan2
- BIRC6 | c.4616C>T p.S1539L | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV101429135; called by muse, mutect2, varscan2
- C11orf87 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs1440447198; called by muse, mutect2, varscan2
- CFH | c.1976G>T p.C659F | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1442479023; called by muse, mutect2
- CNTNAP4 | c.1579G>T p.D527Y | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56700835; called by muse, mutect2, varscan2
- DLGAP3 | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 8/165 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.202); catalogued as rs1312181558; called by muse, mutect2
- FPR1 | c.602G>A p.R201K | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.407); catalogued as rs1461765570, COSV100494122; called by muse, mutect2, varscan2
- FSCN1 | c.1353C>A p.F451L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV61017695; called by muse, mutect2
- GABRB3 | c.650G>T p.R217L | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as CM021606; called by muse, mutect2, varscan2
- GXYLT1 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1204486576, COSV99788998; called by muse, mutect2, varscan2
- H2AC4 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52518518, COSV52519334; called by muse, varscan2
- IGF2R | c.6160G>T p.V2054F | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV63630668; called by muse, mutect2, varscan2
- IGHV2-5 | c.175C>A p.R59S | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs369263980; called by muse, mutect2
- KCNC3 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1338146006, COSV100979144; called by muse, mutect2
- KCNT2 | c.2813G>C p.R938T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as COSV54090537; called by muse, mutect2, varscan2
- LSMEM1 | c.46G>C p.D16H | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs1263048617, COSV100456297; called by muse, mutect2, varscan2
- MAGI2 | c.3895G>A p.E1299K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.956); catalogued as COSV100836997; called by muse, mutect2, varscan2
- MALT1 | c.1145C>T p.S382L | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61934039; called by muse, mutect2
- MECOM | c.1252G>A p.E418K (on ENST00000468789 / NM_001105078.4; = p.E606K on NM_004991.4) | Missense Mutation (SNP) | VAF 4/75 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as COSV52962452; called by muse, mutect2
- MMP1 | c.401T>C p.I134T | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs753617940; called by muse, mutect2, varscan2
- MRPS2 | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.101); catalogued as rs931429034; called by muse, mutect2, varscan2
- MUC16 | c.28406C>G p.S9469C | Missense Mutation (SNP) | VAF 54/230 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.95); catalogued as rs772659965; called by muse, varscan2
- OAS3 | c.898G>C p.D300H | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1318129832, COSV57446542; called by muse, mutect2
- OR1E1 | c.730C>A p.H244N | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59459455; called by muse, mutect2, varscan2
- OR2AK2 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 40/373 reads (11%) | catalogued as COSV63547705; called by muse, mutect2
- OR2AK2 | c.332A>T p.E111V | Missense Mutation (SNP) | VAF 40/373 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747628354; called by muse, mutect2
- OR4A15 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.077); catalogued as rs1263727903, COSV59034639, COSV59037308; called by muse, mutect2, varscan2
- OR4C12 | c.925G>T p.D309Y | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.232); catalogued as COSV58859337, COSV58861087; called by muse, mutect2, varscan2
- OR4D10 | c.699G>T p.R233S | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV73260229; called by muse, mutect2, varscan2
- OR4D9 | c.224C>A p.S75Y | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV61434753; called by muse, mutect2, varscan2
- ORC3 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs375214415; called by muse, mutect2, varscan2
- PCLO | c.7948G>T p.A2650S | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV61650170; called by muse, mutect2, varscan2
- PHEX | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV65075650; called by muse, mutect2, varscan2
- RBM11 | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 27/233 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); catalogued as COSV68748317; called by muse, varscan2
- RHBDL3 | c.902G>T p.C301F | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1297980739; called by muse, mutect2, varscan2
- RYR2 | c.1237T>G p.S413A | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.188); catalogued as CM0910997; called by muse, mutect2, varscan2
- SCN10A | c.5868del p.*1957Sfs*20 (on ENST00000449082; = p.*1957Sfs*? on NM_006514.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/86 reads (14%) | catalogued as rs1439987908; called by mutect2, varscan2
- SHROOM4 | c.970A>G p.R324G | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs781821138; called by muse, mutect2
- SLFN13 | c.175G>A p.G59R | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1346448165; called by muse, mutect2
- SLITRK1 | c.472G>T p.V158L | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65676977; called by muse, mutect2
- SORL1 | c.3476G>T p.R1159L | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.737); catalogued as rs527617199, COSV52759248; called by muse, mutect2
- SPEG | c.9094C>A p.P3032T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56679298; called by muse, mutect2, varscan2
- TG | c.1118C>A p.S373Y | Missense Mutation (SNP) | VAF 41/332 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV55069248; called by muse, mutect2, varscan2
- TICRR | c.2815G>T p.V939L | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.289); catalogued as rs761741159; called by muse, mutect2
- TMEFF1 | c.1085G>T p.R362L | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV56867383; called by muse, mutect2
- TRPM3 | c.4628T>A p.V1543E (on ENST00000357533 / NM_001366142.2; = p.V1398E on NM_020952.6) | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.211); catalogued as COSV62585167; called by muse, mutect2, varscan2
- TTLL5 | c.3340G>T p.G1114W | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as rs751858200, COSV54031115; called by muse, mutect2, varscan2
- ZDHHC2 | c.460G>C p.D154H | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV50498869; called by muse, mutect2
- ZNF142 | c.2320C>T p.H774Y (on ENST00000411696 / NM_001379660.1; = p.H574Y on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV101376968; called by muse, mutect2
- ZNF638 | c.109A>G p.M37V | Missense Mutation (SNP) | VAF 27/225 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.824); catalogued as rs139959335; called by muse, mutect2, varscan2
- ZNF708 | c.904C>G p.H302D | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV63606955; called by muse, mutect2, varscan2
- ZNF71 | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100045873, COSV60148398; called by muse, mutect2, varscan2
- ACO1 | c.2096G>A p.R699K | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0.014); called by muse, mutect2
- ACRBP | c.401C>T p.T134I | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- ALG13 | c.2905G>C p.D969H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ANPEP | c.709C>T p.L237F | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- APBB3 | c.697G>A p.D233N (on ENST00000357560 / NM_133173.2; = p.D240N on NM_006051.3) | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2
- ATP10B | c.532A>G p.M178V | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC50 | c.1348G>A p.G450S (on ENST00000392455 / NM_178335.3; = p.G274S on NM_174908.4) | Missense Mutation (SNP) | VAF 51/346 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CDC73 | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CDH13 | c.1264G>T p.G422W | Missense Mutation (SNP) | VAF 40/328 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHD3 | c.2911G>A p.D971N | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CNKSR2 | c.2285C>A p.A762D | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- CPZ | c.711G>A p.M237I (on ENST00000360986 / NM_001014447.3; = p.M226I on NM_003652.3) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.029); called by muse, mutect2
- CSRP1 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- DNAH9 | c.3717G>T p.E1239D | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2
- EFCAB5 | c.2342T>A p.I781N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- EGFL6 | c.1306G>T p.V436F | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- EIF2AK4 | c.1162G>T p.A388S | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- ERRFI1 | c.94A>C p.T32P | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.031); called by muse, mutect2
- FANCI | c.975G>T p.Q325H | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); called by muse, mutect2
- GLUD2 | c.1032C>A p.D344E | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- GOLGA2 | c.2938G>A p.D980N | Missense Mutation (SNP) | VAF 19/218 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); called by muse, mutect2
- GRM1 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- HENMT1 | c.533A>T p.D178V | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- IMPDH2 | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- LAMA3 | c.5461G>C p.D1821H (on ENST00000313654 / NM_198129.4; = p.D212H on NM_000227.6) | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LARP4 | c.1970C>T p.P657L | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- LRP5 | c.4163G>T p.G1388V | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.089); called by muse, mutect2
- LRRN3 | c.1100G>T p.S367I | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- LRRTM4 | c.1051A>G p.S351G | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- MAP7 | c.1119G>C p.K373N | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MRPL45 | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 8/190 reads (4%) | called by muse, mutect2
- MUC16 | c.13605A>G p.I4535M | Missense Mutation (SNP) | VAF 15/195 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.353); called by muse, mutect2
- MYL3 | c.110T>G p.F37C | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2
- NANOS2 | c.50A>T p.Q17L | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.054); called by muse, mutect2
- NAV1 | c.2026C>G p.P676A | Missense Mutation (SNP) | VAF 70/232 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- NCOA1 | c.1999G>T p.A667S | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.89); PolyPhen benign (0.009); called by muse, mutect2
- NIBAN2 | c.1387G>T p.E463* | Nonsense Mutation (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- NLRC4 | c.473T>A p.L158Q | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NUTM1 | c.1630C>A p.L544I | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- OR2B11 | c.189G>T p.M63I | Missense Mutation (SNP) | VAF 86/278 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR51G2 | c.444G>T p.R148S | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- PCDHA5 | c.2347G>T p.D783Y | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- PDAP1 | c.468G>C p.K156N | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2
- PFAS | c.1905G>C p.K635N | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.161); called by muse, mutect2
- PIGP | c.372G>T p.Q124H (on ENST00000464265 / NM_153681.2; = p.Q74H on NM_016430.4) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PKP4 | c.2141G>T p.C714F | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLEKHA7 | c.2855C>T p.S952F | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PPP1R9A | c.1213A>T p.R405W | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PYROXD1 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- RBM5 | c.1397A>T p.E466V | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SEC24C | c.1799G>T p.S600I | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); called by muse, mutect2
- SIAH2 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- SLC17A8 | c.282C>A p.C94* | Nonsense Mutation (SNP) | VAF 7/79 reads (9%) | called by muse, mutect2
- SLIT3 | c.3668C>T p.P1223L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- SPANXN4 | c.47C>A p.P16H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SSTR1 | c.1171C>T p.L391F | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- ST18 | c.2117C>G p.P706R | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SULT4A1 | c.431A>T p.Q144L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2
- TENM4 | c.3662A>C p.N1221T | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- THY1 | c.227C>A p.S76Y | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- TMC2 | c.2320T>A p.Y774N | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TRAV34 | c.127T>A p.C43S | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRPC5 | c.1351T>A p.S451T | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.963); called by muse, mutect2
- UBE2NL | c.116T>A p.I39N | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- UNC80 | c.476G>T p.G159V | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VWA3B | c.1132G>T p.V378F | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ZC3H13 | c.3043G>A p.D1015N | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- ZNF711 | c.2226C>A p.F742L | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ABCB11 | c.3306G>T p.S1102= | Silent (SNP) | VAF 6/87 reads (7%) | catalogued as rs377691925, COSV55587341; called by muse, mutect2
- CACNA2D3 | c.825G>A p.A275= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as rs923437886, COSV55523133; called by muse, mutect2, varscan2
- CATIP | c.801C>T p.I267= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs1412952051; called by muse, mutect2
- CEACAM7 | c.630C>T p.D210= | Silent (SNP) | VAF 51/201 reads (25%) | called by muse, mutect2, varscan2
- COL2A1 | c.3864C>T p.L1288= | Silent (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- ENPP6 | c.1026C>T p.S342= | Silent (SNP) | VAF 14/109 reads (13%) | called by muse, mutect2, varscan2
- EP300 | c.5034G>A p.E1678= | Silent (SNP) | VAF 12/134 reads (9%) | called by muse, mutect2, varscan2
- EPN2 | c.393G>T p.V131= | Silent (SNP) | VAF 22/121 reads (18%) | called by muse, mutect2, varscan2
- FAM47B | c.792C>A p.P264= | Silent (SNP) | VAF 17/143 reads (12%) | called by muse, mutect2, varscan2
- FCRL3 | c.1359A>T p.A453= | Silent (SNP) | VAF 67/312 reads (21%) | catalogued as COSV63843059; called by muse, mutect2, varscan2
- HCFC1 | c.285G>T p.L95= | Silent (SNP) | VAF 12/142 reads (8%) | called by muse, mutect2
- IGSF10 | c.3192G>T p.L1064= | Silent (SNP) | VAF 14/94 reads (15%) | called by muse, mutect2, varscan2
- IL7R | c.774C>A p.I258= | Silent (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- KCNMA1 | c.3021C>T p.N1007= (on ENST00000286628 / NM_001161352.2; = p.N949= on NM_002247.4) | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs369363787; ClinVar: likely benign; called by muse, mutect2, varscan2
- LPAR3 | c.372C>T p.A124= | Silent (SNP) | VAF 40/423 reads (9%) | catalogued as rs368870250; called by muse, mutect2
- MAGEA4 | c.744C>A p.T248= | Silent (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- MBOAT1 | c.1107C>T p.P369= | Silent (SNP) | VAF 11/75 reads (15%) | called by muse, mutect2, varscan2
- MLLT6 | c.1809T>G p.S603= | Silent (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- MSANTD1 | c.369C>G p.P123= | Silent (SNP) | VAF 9/43 reads (21%) | called by muse, varscan2
- MSI1 | c.366G>T p.V122= | Silent (SNP) | VAF 14/119 reads (12%) | called by muse, mutect2, varscan2
- MYH13 | c.3420C>A p.R1140= | Silent (SNP) | VAF 19/147 reads (13%) | called by muse, mutect2, varscan2
- MYO1E | c.177C>T p.V59= | Silent (SNP) | VAF 8/140 reads (6%) | catalogued as rs1207392295; called by muse, mutect2
- NXF3 | c.972C>T p.A324= | Silent (SNP) | VAF 48/325 reads (15%) | catalogued as rs759646820; called by muse, mutect2, varscan2
- OCA2 | c.2439C>G p.G813= | Silent (SNP) | VAF 12/79 reads (15%) | called by muse, mutect2, varscan2
- OR2V2 | c.553T>C p.L185= | Silent (SNP) | VAF 16/186 reads (9%) | catalogued as rs778791176; called by muse, mutect2
- OR52E8 | c.780A>T p.A260= | Silent (SNP) | VAF 13/113 reads (12%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.1812G>T p.L604= | Silent (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2, varscan2
- PDYN | c.504C>A p.P168= | Silent (SNP) | VAF 15/144 reads (10%) | called by muse, mutect2, varscan2
- PNCK | c.303C>A p.R101= (on ENST00000340888 / NM_001366975.1; = p.R184= on NM_001039582.3) | Silent (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- PPP2R5E | c.309C>T p.S103= | Silent (SNP) | VAF 17/138 reads (12%) | called by muse, mutect2, varscan2
- PRF1 | c.588C>T p.A196= | Silent (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2
- PSME2 | c.33G>T p.G11= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- RESF1 | c.1749A>T p.L583= | Silent (SNP) | VAF 8/34 reads (24%) | called by muse, varscan2
- RYR3 | c.5544C>A p.L1848= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV101211777; called by muse, mutect2, varscan2
- SAGE1 | c.1392T>A p.L464= | Silent (SNP) | VAF 16/102 reads (16%) | called by muse, mutect2, varscan2
- SCN4A | c.519C>G p.L173= | Silent (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- SCN5A | c.2154T>C p.F718= | Silent (SNP) | VAF 8/72 reads (11%) | called by mutect2, varscan2
- SHCBP1L | c.498T>C p.S166= | Silent (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2
- SLC36A1 | c.1347G>T p.V449= | Silent (SNP) | VAF 13/101 reads (13%) | called by muse, mutect2, varscan2
- SPANXN4 | c.48C>G p.P16= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV100980921; called by muse, mutect2, varscan2
- SPATA18 | c.727C>T p.L243= | Silent (SNP) | VAF 16/186 reads (9%) | called by muse, mutect2
- SYS1 | c.252C>T p.F84= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as rs142015382; called by muse, mutect2
- TENM1 | c.5695C>A p.R1899= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV64432948; called by muse, mutect2, varscan2
- ZBTB39 | c.318T>C p.A106= | Silent (SNP) | VAF 25/177 reads (14%) | called by muse, mutect2, varscan2
- ZSCAN10 | c.468C>A p.P156= (on ENST00000252463; = p.P211= on NM_032805.3) | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV99374320; called by muse, mutect2
- ZNF415 | c.*2A>G | 3'UTR (SNP) | VAF 6/65 reads (9%) | called by muse, mutect2
